Surgical pathology report (de-identified scan), TCGA case TCGA-DD-A1EE, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site Mayo Clinic - Rochester, specimen TCGA-DD-A1EE-01A (Primary Tumor).

[page 1 of 4]
Carcinoma, hepatocellular, NOS 8170/3
Site Code: Liver C22-0 1/19/11 for

Patient Key:
Surgical date:

TISSUE DESCRIPTION:

A1 A2 B1 B2 B3 B4 B5 B6 B7 C1 D1
D2 E1 F1 F2 F3 F4 F5 F6 F7 F8 F9 F10 F11 F12 F13 F14 F15 F16
Portion liver segment VII (540 grams; 13.8 x 11.2 x 9.7 cm),
tissue from liver segment V (biopsy, No. 1 - 1.5 x 0.9 x 0.7 cm;
No. 2 - 1.0 x 0.8 x 0.6 cm), tissue from liver segment VIII
(core biopsies - 1.0 cm in length and 1.5 cm in length), tissue
from the spleen (biopsy, 0.4 x 0.4 x 0.2 cm), and gallbladder
(9.4 x 4.7 x 2.2 cm with a cystic duct lymph node, 3.4 x 2.6 x
2.0 cm).

DIAGNOSIS:

Liver, segment VII, resection: Grade 3 (of 4) hepatocellular
carcinoma forming a dominant mass, 9.7 x 9.5 x 8.4 cm. Multiple
(at least 25) smaller tumor nodules are identified adjacent to
the larger mass, as well as away from it, ranging in size from
0.1 cm to 2.2 cm. Background liver shows cirrhosis with nodular
regeneration. Surgical margins are negative for tumor (closest 1
mm). Liver, segment V (No. 2), biopsy: Grade 2-3 (of 4)
hepatocellular carcinoma, 0.6 x 0.6 x 0.5 cm. Liver, segment
VIII, needle core biopsy: Grade 2-3 (of 4) hepatocellular
carcinoma. Liver, segment V (No. 1), biopsy: Cavernous
hemangioma, 0.8 x 0.6 x 0.5 cm.

Spleen, biopsy: Benign splenic tissue.

Gallbladder, cholecystectomy: Mild chronic cholecystitis and
cholesterolosis. A single cystic duct lymph node is benign.

UIPAA Discrepancy		X

hw

[page 2 of 4]
Patient Key:
Surgical date:

TISSUE DESCRIPTION:

A1 A2 B1 B2 B3 B4 B5 B6 B7 C1 D1
D2 E1 F1 F2 F3 F4 F5 F6 F7 F8 F9 F10 F11 F12 F13 F14 F15 F16
Portion liver segment VII (540 grams; 13.8 x 11.2 x 9.7 cm),
tissue from liver segment V (biopsy, No. 1 - 1.5 x 0.9 x 0.7 cm;
No. 2 - 1.0 x 0.8 x 0.6 cm), tissue from liver segment VIII
(core biopsies - 1.0 cm in length and 1.5 cm in length), tissue
from the spleen (biopsy, 0.4 x 0.4 x 0.2 cm), and gallbladder
(9.4 x 4.7 x 2.2 cm with a cystic duct lymph node, 3.4 x 2.6 x
2.0 cm).

DIAGNOSIS:

Liver, segment VII, resection: Grade 3 (of 4) hepatocellular
carcinoma forming a dominant mass, 9.7 x 9.5 x 8.4 cm. Multiple
(at least 25) smaller tumor nodules are identified adjacent to
the larger mass, as well as away from it, ranging in size from
0.1 cm to 2.2 cm. Background liver shows cirrhosis with nodular
regeneration. Surgical margins are negative for tumor (closest 1
mm). Liver, segment V (No. 2), biopsy: Grade 2-3 (of 4)
hepatocellular carcinoma, 0.6 x 0.6 x 0.5 cm. Liver, segment
VIII, needle core biopsy: Grade 2-3 (of 4) hepatocellular
carcinoma. Liver, segment V (No. 1), biopsy: Cavernous
hemangioma, 0.8 x 0.6 x 0.5 cm.

Spleen, biopsy: Benign splenic tissue.

Gallbladder, cholecystectomy: Mild chronic cholecystitis and
cholesterolosis. A single cystic duct lymph node is benign.

[page 3 of 4]
Liver • Digestive System CAP Approved

* Data elements *with asterisks* are *not required* for accreditation purposes for the Commission on Cancer. These elements may be clinically important, but are not yet validated or regularly used in patient management. Alternatively, the necessary data may not be available to the pathologist at the time of pathologic assessment of this specimen.

LIVER: Resection

Patient name: *(to be de-identified)*

Surgical pathology number:

MACROSCOPIC

Specimen Type

- ☒ Right lobectomy
- ☐ Extended right lobectomy
- ☐ Medial segmentectomy
- ☐ Left lateral segmentectomy
- ☐ Total left lobectomy
- ☐ Explanted liver
- ☐ Other (specify): _____
- ☐ Not specified

Focality

- ☐ Solitary (specify location): _____
- ☒ Multiple (specify location): segment VII (VII, V)

Tumor Size

Greatest dimension: 9.1 cm

*Additional dimensions: 9.5 x 8.4 cm

☐ Cannot be determined (see Comment)

MICROSCOPIC

Histologic Type

- ☒ Hepatocellular carcinoma
- ☐ Fibrolamellar hepatocellular carcinoma variant (specify): _____
- ☐ Combined hepatocellular and cholangiocarcinoma
- ☐ Cholangiocarcinoma, intrahepatic
- ☐ Bile duct cystadenocarcinoma
- ☐ Undifferentiated carcinoma
- ☐ Other (specify): _____
- ☐ Carcinoma, type cannot be determined

Histologic Grade

- ☐ Not applicable
- ☐ GX: Cannot be assessed
- ☐ GI: Well differentiated
- ☐ GII: Moderately differentiated
- ☒ GIII: Poorly differentiated
- ☐ GIV: Undifferentiated/anaplastic
- ☐ Other (specify): _____

[page 4 of 4]
Pathologic Staging (pTNM)

Primary Tumor (pT)

- ☐ pTX: Cannot be assessed
☐ pT0: No evidence of primary tumor
☐ pT1: Solitary tumor with no vascular invasion
☒ pT2: Solitary tumor with vascular invasion or multiple tumors none more than 5 cm
☒ pT3: Multiple tumors more than 5 cm or tumor involving a major branch of the portal or hepatic vein(s)
☐ pT4: Tumor(s) with direct invasion of adjacent organs other than the gallbladder or perforation of visceral peritoneum

Regional Lymph Nodes (pN)

- ☒ pNX: Cannot be assessed
☐ pN0: No regional lymph node metastasis
☐ pN1: Regional lymph node metastasis
Specify: Number examined: ____
Number involved: ____

Distant Metastasis (pM)

- ☒ pMX: Cannot be assessed
☐ pM1: Distant metastasis

*Specify site(s), if known: _____

Margins (check all that apply)

Parenchymal Margin

- ☐ Cannot be assessed
☒ Uninvolved by invasive carcinoma
Distance of invasive carcinoma from closest margin: 1.2 mm
Specify margin: _____

☐ Involved by invasive carcinoma

Bile Duct Margin (Cholangiocarcinoma Only)

- ☒ Cannot be assessed
☐ Uninvolved by invasive carcinoma
* ☐ Carcinoma in situ absent
* ☐ Carcinoma in situ present
☐ Involved by invasive carcinoma

Other Margin

- Specify margin: _____
☐ Cannot be assessed
☐ Uninvolved by invasive carcinoma
☐ Involved by invasive carcinoma

***Venous (Large Vessel) Invasion (V)**

- * ☐ Absent
* ☐ Present
* ☒ Indeterminate

***Additional Pathologic Findings (check all that apply)**

- * ☐ None identified
* ☐ Hepatocellular dysplasia
* ☐ Ductal dysplasia
* ☒ Cirrhosis/fibrosis
* ☐ Iron overload
* ☐ Hepatitis (specify type): _____
* ☐ Other (specify): seg V cavernous hemangioma

Source: NCI Genomic Data Commons file 3e316f40-7922-4247-a4c4-661ce66c39c5 (TCGA-DD-A1EE.EC55BB6D-4704-48D6-9C37-E82AADE685F7.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).